Somatic mutation profile of tumor specimen C3N-00306-02 (aliquot CPT0011290008) from CPTAC case C3N-00306, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.8 years (18,561 days).
Specimen C3N-00306-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1247427d-1835-467d-b0ea-b3013368e850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00306-31 (Blood Derived Normal), aliquot CPT0011380006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc9ce5b5-788f-4a46-8971-1ca83c8f7df4

The open-access MAF lists 139 somatic variants for this specimen: 88 protein-altering or splice-affecting, 27 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Intron 9, RNA 5, 3'UTR 5, Nonsense Mutation 5, Frame Shift Del 3, 5'UTR 3, Frame Shift Ins 3, 5'Flank 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.6502G>A p.V2168M | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118192176, CM981781, COSV62094129; ClinVar: pathogenic / drug response / risk factor; called by muse, mutect2
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 67/344 reads (19%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- AGO2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1224870621; called by muse, mutect2
- ANKFN1 | c.3280G>A p.D1094N (on ENST00000653862; = p.D947N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs758031860; called by muse, mutect2
- C6 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1454191182, COSV54706841; called by muse, mutect2, varscan2
- CWC22 | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55432483; called by muse, mutect2, varscan2
- CYB561D2 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1391556951; called by muse, mutect2
- ENPP3 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716769, COSV62956659; called by muse, mutect2, varscan2
- FAT1 | c.5793C>G p.Y1931* | Nonsense Mutation (SNP) | VAF 30/259 reads (12%) | catalogued as rs369044055; called by muse, mutect2, varscan2
- FRS2 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV54730297; called by muse, mutect2
- GHR | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50126231; called by muse, mutect2, varscan2
- LRRN3 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57820560; called by muse, mutect2, varscan2
- NACC2 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs745861172; called by muse, mutect2, varscan2
- OR10A4 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1158050791; called by muse, mutect2
- OR2M4 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV60708269; called by muse, mutect2
- OR4K2 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100064777; called by muse, mutect2
- PCDHA3 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 39/819 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV63546505; called by muse, mutect2
- PCDHB10 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1554284030; called by muse, mutect2
- PCDHGA7 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV53927246; called by muse, mutect2
- PCDHGB6 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768592770; called by muse, mutect2
- PTEN | c.716T>A p.M239K | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.39); catalogued as CM1513165, COSV64298458; called by muse, mutect2
- SCRIB | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); catalogued as CM125339, COSV57588270; called by muse, mutect2
- SLC11A2 | c.1078-6T>A | Splice Region (SNP) | VAF 17/233 reads (7%) | catalogued as rs1457000554; called by muse, mutect2
- SOBP | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV57997184; called by muse, mutect2
- THOC2 | c.1552C>G p.Q518E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV55543997; called by muse, mutect2, varscan2
- ZIC4 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV67174639; called by muse, mutect2
- ZNF551 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs760992855; called by muse, mutect2
- ZNF704 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751794218, COSV59922674; called by muse, mutect2
- ZNF804B | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199714594, COSV60821142; called by muse, mutect2
- ABCB4 | c.1149A>T p.R383S | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.1744del p.E582Sfs*120 | Frame Shift Del (DEL) | VAF 44/423 reads (10%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.6652T>A p.L2218I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2
- AKIRIN2 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2
- ANGPT1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.038); called by muse, mutect2
- ANKRD30A | c.3995G>A p.W1332* (on ENST00000611781; = p.W1276* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- ANKRD30B | c.2418T>C p.S806= | Splice Region (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- ANKRD30B | c.2670A>T p.L890F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, varscan2
- ARHGAP31 | c.138_139del p.E46Dfs*54 | Frame Shift Del (DEL) | VAF 75/378 reads (20%) | called by pindel, varscan2
- ARMC4 | c.2323A>G p.N775D | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CCAR1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT6B | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CDKN2A | c.288dup p.L97Afs*23 | Frame Shift Ins (INS) | VAF 64/542 reads (12%) | called by mutect2, pindel
- CFAP126 | c.105T>A p.H35Q | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHL1 | c.2458G>T p.V820F (on ENST00000397491 / NM_001253387.1; = p.V836F on NM_006614.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CIT | c.5303A>C p.N1768T | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- ELAPOR2 | c.1193G>T p.C398F (on ENST00000450689 / NM_001142749.3; = p.C231F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELMO1 | c.299A>T p.K100M | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EVC2 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA4 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- FAM135B | c.2377G>T p.G793* | Nonsense Mutation (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- FCGBP | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2
- FSIP2 | c.13927C>A p.Q4643K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GCG | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- GJE1 | c.196A>G p.N66D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, mutect2
- GK2 | c.1329T>A p.H443Q | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GPR21 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GRK3 | c.1904A>T p.E635V | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); called by muse, mutect2
- HIVEP3 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.086); called by muse, mutect2
- HLA-E | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HTR3E | c.1371G>T p.*457Yext*35 (on ENST00000415389 / NM_001256613.1; = p.*472Yext*35 on NM_182589.2) | Nonstop Mutation (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- IGLV3-22 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2
- IGSF10 | c.6092T>C p.V2031A | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL20RA | c.500A>C p.D167A | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); called by muse, mutect2
- KMT2A | c.11671G>C p.E3891Q | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MAML2 | c.2306A>G p.Q769R | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MARCHF9 | c.899dup p.A301Sfs*91 | Frame Shift Ins (INS) | VAF 20/208 reads (10%) | called by mutect2, pindel
- MDN1 | c.11435G>T p.R3812L | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLYCD | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC5B | c.6179C>A p.T2060K | Missense Mutation (SNP) | VAF 55/530 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2
- MYH15 | c.2856dup p.R953Afs*6 | Frame Shift Ins (INS) | VAF 46/359 reads (13%) | called by mutect2, pindel, varscan2
- OR2T8 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PDE4B | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLEKHG5 | c.1325T>A p.V442E (on ENST00000400915 / NM_001042663.3; = p.V405E on NM_020631.6) | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- PREX1 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEPTIN10 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC12A1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK2 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SMG1 | c.10531G>C p.V3511L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- SPIDR | c.660G>T p.M220I | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- TMPRSS9 | c.3266A>G p.Q1089R (on ENST00000648592; = p.Q1055R on NM_182973.2) | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2
- VWDE | c.2431C>G p.Q811E | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP2 | c.8961del p.K2987Nfs*47 (on ENST00000628543; = p.K3162Nfs*47 on NM_152381.6) | Frame Shift Del (DEL) | VAF 18/200 reads (9%) | called by mutect2, pindel
- ZBTB14 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2
- ZNF208 | c.1618C>T p.L540F | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ZNF276 | c.1244C>A p.P415H (on ENST00000443381 / NM_001113525.2; = p.P340H on NM_152287.4) | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF429 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- ZNF493 | c.1274C>G p.A425G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ZNF99 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALDH3A1 | c.174C>T p.N58= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs144035368; called by muse, mutect2, varscan2
- AMELX | c.204G>C p.V68= | Silent (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- CCDC88C | c.4516C>T p.L1506= | Silent (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- DNAH11 | c.330G>T p.G110= | Silent (SNP) | VAF 27/340 reads (8%) | catalogued as rs952333583, COSV60957350; called by muse, mutect2
- DNAH5 | c.12651T>C p.F4217= | Silent (SNP) | VAF 67/674 reads (10%) | called by muse, mutect2, varscan2
- FZD2 | c.1218C>G p.L406= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- KRT32 | c.312C>T p.N104= | Silent (SNP) | VAF 20/377 reads (5%) | catalogued as rs370709868; called by muse, mutect2
- MRPL48 | c.54G>A p.K18= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- MYLK | c.2130C>T p.L710= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as COSV60614107; called by muse, mutect2
- NR5A2 | c.1017G>C p.L339= (on ENST00000367362 / NM_205860.3; = p.L293= on NM_003822.5) | Silent (SNP) | VAF 21/366 reads (6%) | called by muse, mutect2
- NXPH2 | c.456C>A p.G152= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- OR2L13 | c.258C>A p.S86= | Silent (SNP) | VAF 31/314 reads (10%) | catalogued as COSV63549465; called by muse, mutect2
- OR5H15 | c.550T>C p.L184= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- OR8H3 | c.144G>A p.L48= | Silent (SNP) | VAF 20/223 reads (9%) | catalogued as COSV100538872; called by muse, mutect2
- PHF21B | c.1482G>A p.L494= | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- PLD5 | c.78C>A p.P26= | Silent (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.1995G>A p.L665= (on ENST00000318304 / NM_177444.3; = p.L659= on NM_003622.4) | Silent (SNP) | VAF 21/281 reads (7%) | catalogued as rs749670136; called by muse, mutect2
- PROX1 | c.873T>A p.S291= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- REG1B | c.231C>A p.T77= | Silent (SNP) | VAF 23/257 reads (9%) | called by muse, mutect2
- SCN10A | c.5013C>A p.L1671= | Silent (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- SLC12A1 | c.2256G>A p.A752= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs149454210; called by muse, mutect2
- SMARCA1 | c.2967A>G p.R989= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, varscan2
- SYT13 | c.681C>T p.L227= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as rs1328233084, COSV50073098; called by muse, mutect2
- TCF23 | c.321G>T p.P107= | Silent (SNP) | VAF 16/271 reads (6%) | catalogued as COSV56078413; called by muse, mutect2
- TMEM186 | c.411C>G p.G137= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs763426684; called by muse, mutect2
- TRBV7-1 | c.309G>A p.Q103= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs756101971; called by muse, mutect2, varscan2
- ZIC1 | c.177C>T p.A59= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as COSV51551133; called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+1982C>G | Intron (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- ACVR2B | c.-14C>T | 5'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- AL669831.1 | n.2669C>T | RNA (SNP) | VAF 32/780 reads (4%) | called by muse, mutect2
- DEPDC5 | c.*707G>A | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- FANCA | c.2222+41G>T | Intron (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2
- GUSBP10 | n.137C>A | RNA (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- GYPA | c.*11A>G | 3'UTR (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- IL4I1 | chr19:49901666 C>T | 5'Flank (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- ITM2B | c.-21G>C | 5'UTR (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2, varscan2
- KANSL1 | c.2542-20T>A | Intron (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- LINC02876 | n.144C>T | RNA (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- LRRC74A | c.217+694G>A | Intron (SNP) | VAF 15/247 reads (6%) | catalogued as rs947920438; called by muse, mutect2
- LSMEM1 | c.128-563C>G | Intron (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- NDRG1 | chr8:133298412 C>A | 5'Flank (SNP) | VAF 31/213 reads (15%) | called by muse, mutect2, varscan2
- NLGN3 | c.-18A>T | 5'UTR (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2523G>T | Intron (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- OR10D1P | n.398T>A | RNA (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- PEX5L | c.22-1557C>G | Intron (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- QKI | c.285+1978G>A | Intron (SNP) | VAF 26/233 reads (11%) | catalogued as rs1335416804; called by muse, mutect2, varscan2
- RAB18 | c.*1779A>G | 3'UTR (SNP) | VAF 6/66 reads (9%) | catalogued as rs544225499; called by mutect2, varscan2
- SMIM22 | n.95C>T | RNA (SNP) | VAF 17/297 reads (6%) | called by muse, mutect2
- TMEM135 | c.*326T>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6532G>T | 3'UTR (SNP) | VAF 56/542 reads (10%) | called by muse, mutect2
- WDPCP | c.2159-48C>T | Intron (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
